Somatic mutation profile of tumor specimen BA2155D (aliquot aq-BA2155D) from BEATAML1.0 case 2402, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.2 years (26,371 days).
Specimen BA2155D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 174ac244-b939-45af-b961-9b5452397dac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3041D (Solid Tissue Normal), aliquot aq-BA3041D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f954f030-4093-4ef5-8fbf-43afc0153346

The open-access MAF lists 20 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.560-2dup p.X187_splice | Splice Site (INS) | VAF 89/210 reads (42%) | hotspot (GDC flag); called by mutect2, varscan2
- CNN3 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 73/131 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.807); catalogued as COSV54734417; called by muse, mutect2, varscan2
- FCRL1 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.067); catalogued as rs759656874; called by muse, mutect2, varscan2
- GATA2 | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 76/129 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM141457, COSV62005311; called by muse, mutect2, varscan2
- HCK | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as rs774699694; called by muse, mutect2, varscan2
- NECTIN4 | c.859G>T p.G287W | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63513329; called by muse, mutect2
- TRRAP | c.5818C>A p.Q1940K (on ENST00000359863 / NM_001244580.1; = p.Q1922K on NM_003496.3) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as COSV100722190; called by muse, mutect2
- TUBA3C | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.394); catalogued as rs201563264, COSV67139779; called by muse, mutect2, varscan2
- CHD7 | c.3383A>G p.H1128R | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CHN1 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- CTNNAL1 | c.1092G>A p.W364* | Nonsense Mutation (SNP) | VAF 35/91 reads (38%) | called by muse, mutect2, varscan2
- FBXO46 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.086); called by muse, mutect2
- MARCHF8 | c.448A>G p.S150G | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PDZD7 | c.2447G>T p.R816L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- REV1 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2
- TPPP | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2
- TTC4 | c.327A>T p.K109N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- UBR5 | c.2884A>G p.I962V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- BRWD3 | c.2231+31dup | Intron (INS) | VAF 24/63 reads (38%) | called by mutect2, varscan2
- WDR90 | c.1966+60G>A | Intron (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2
